Gene-level copy-number profile of tumor specimen TCGA-OR-A5J7-01A from TCGA case TCGA-OR-A5J7, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 30.9 years (11,279 days).
Specimen TCGA-OR-A5J7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.3550e483-fe1a-4a5f-a0ca-0560c7a43813.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5J7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6311129-e1db-4885-9b8a-35191e273586

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 3,083; copy number 3: 3; copy number 4: 26,895; copy number 5: 120; copy number 6: 20,765; copy number 7: 512; copy number 8: 5,449; copy number 9: 2,122; copy number 10: 133; copy number 11: 687; copy number 15: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5J7-01A-11D-A29H-01): tumor purity 0.84, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,260,442–181,265,145, 1 gene: LINC02500.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,980 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,285,410–38,515,934, 6 genes, copy number 9: GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6.
- chr2:64,086,353–65,056,168, 32 genes, copy number 9: AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3, AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576.
- chr2:196,967,017–232,344,350, 677 genes, copy number 9–11 (broad region; genes not listed).
- chr3:90,030,284–90,030,495, 1 gene, copy number 10: U3.
- chr3:183,806,457–184,582,408, 44 genes, copy number 9: YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839, LINC01840, EPHB3.
- chr5:58,198–17,502,363, 314 genes, copy number 9 (broad region; genes not listed).
- chr5:58,582,221–64,768,691, 65 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:43,477,523–44,155,519, 28 genes, copy number 9 (within-gene range 6–9): TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B.
- chr7:32,427,901–33,109,404, 24 genes, copy number 9: AC018637.1, AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9.
- chr7:33,128,988–33,277,091, 3 genes, copy number 9: AC074338.1, RNA5SP229, AC007312.1.
- chr7:95,542,145–96,110,322, 4 genes, copy number 9 (within-gene range 6–9): AC002451.2, AC002451.1, PDK4, DYNC1I1.
- chr9:127,794,597–128,255,248, 25 genes, copy number 10 (within-gene range 6–10): FPGS, ENG, AL162586.1, Y_RNA, RNA5SP296, AK1, AL157935.2, MIR4672, ST6GALNAC6, ST6GALNAC4, PIP5KL1, AL157935.1, DPM2, FAM102A, AL360268.2, NAIF1, SLC25A25, AL360268.1, SLC25A25-AS1, PTGES2, PTGES2-AS1, LCN2, C9orf16, CIZ1, DNM1.
- chr10:44,712–38,783,108, 675 genes, copy number 11 (broad region; genes not listed).
- chr10:100,907,174–103,090,222, 83 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr10:115,093,365–119,459,745, 65 genes, copy number 9 (broad region; genes not listed).
- chr12:51,590,266–93,894,840, 896 genes, copy number 9–10 (within-gene range 6–10) (broad region; genes not listed).
- chr19:1,782,075–2,341,172, 38 genes, copy number 15 (within-gene range 7–15): ATP8B3, REXO1, AC012615.2, MIR1909, AC012615.6, AC012615.3, KLF16, AC012615.4, AC012615.1, AC012615.5, ABHD17A, SCAMP4, ADAT3, CSNK1G2, CSNK1G2-AS1, BTBD2, AC005306.1, AC004678.2, AC004678.1, AC007136.1, MKNK2, MOB3A, IZUMO4, AP3D1, DOT1L, AC004490.1, PLEKHJ1, MIR1227, MIR6789, SF3A2, AMH, MIR4321, JSRP1, OAZ1, AC005258.1, PEAK3, LINGO3, AC104530.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
